Somatic mutation profile of tumor specimen TCGA-D5-6932-01A (aliquot TCGA-D5-6932-01A-11D-1924-10) from TCGA case TCGA-D5-6932, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 69.7 years (25,466 days).
Specimen TCGA-D5-6932-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 280c8efb-4faf-4bf3-bab2-9d2df116b718.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6932-10A (Blood Derived Normal), aliquot TCGA-D5-6932-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ee3602a-c146-4379-a767-3e101a178a04

The open-access MAF lists 138 somatic variants for this specimen: 111 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 25, Nonsense Mutation 6, Frame Shift Del 6, Nonstop Mutation 2, Splice Region 1, Splice Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 42/64 reads (66%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/96 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAGEC1 | c.3138A>C p.K1046N | Missense Mutation (SNP) | VAF 15/22 reads (68%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs753057119, COSV53569304, COSV53569381; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 11/19 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs756314278, COSV56017752; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4007G>A p.G1336D | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV65877440, COSV65878482; called by muse, mutect2, varscan2
- ADCY6 | c.568C>A p.L190M | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100326428; called by muse, mutect2, varscan2
- ADGRV1 | c.8156G>A p.G2719E | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs1271836681, COSV101315562; called by muse, mutect2, varscan2
- ANGPTL8 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs536232063, COSV52949320; called by muse, mutect2, varscan2
- ANKRD55 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773050862, COSV61944438; called by muse, mutect2, varscan2
- APBB3 | c.1253C>A p.S418Y (on ENST00000357560 / NM_133173.2; = p.S425Y on NM_006051.3) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV60365926; called by muse, mutect2, varscan2
- BBOX1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764375198, COSV54192621; called by mutect2, varscan2
- BCAS3 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs377752373; called by muse, mutect2, varscan2
- BNC2 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV66152537; called by muse, mutect2, varscan2
- C12orf50 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as rs758912316, COSV53893525; called by muse, mutect2, varscan2
- C5orf22 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV57599348; called by muse, mutect2, varscan2
- CAPN9 | c.1722C>T p.D574= | Splice Region (SNP) | VAF 13/52 reads (25%) | catalogued as rs995056082, COSV55236778; called by muse, mutect2, varscan2
- CCDC62 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759641693, COSV53430941; called by muse, mutect2, varscan2
- CCSAP | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52910013, COSV52910584; called by muse, mutect2, varscan2
- CFAP20 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52631233; called by muse, mutect2, varscan2
- CLCA1 | c.2534A>T p.Q845L | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV52329412; called by muse, mutect2, varscan2
- COL27A1 | c.2475A>C p.L825F | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV61928839; called by muse, mutect2, varscan2
- CSPG4 | c.5557C>T p.R1853W | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371534014; called by muse, mutect2, varscan2
- DENND2A | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1433032642, COSV52055489; called by muse, mutect2, varscan2
- DGKI | c.1745A>C p.K582T | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV55963807; called by muse, mutect2, varscan2
- DNAH8 | c.4064A>G p.K1355R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV100543668; called by muse, mutect2, varscan2
- EIF3B | c.2103G>C p.Q701H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV100703575; called by muse, mutect2, varscan2
- ERBB4 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.84); catalogued as COSV53558396; called by muse, mutect2, varscan2
- FAM149A | c.1815G>T p.K605N (on ENST00000356371 / NM_001367768.2; = p.K314N on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV57028961; called by muse, mutect2, varscan2
- FREM2 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99747264; called by muse, mutect2, varscan2
- FREM2 | c.2299C>A p.P767T | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV54844834; called by muse, mutect2, varscan2
- FRS3 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442658; called by muse, mutect2, varscan2
- FRS3 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442660; called by muse, mutect2
- FSCB | c.2291A>C p.Q764P | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV61218977; called by muse, mutect2, varscan2
- GALNT17 | c.1587C>A p.D529E | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100352651; called by muse, mutect2, varscan2
- GALNTL5 | c.1319T>A p.V440E | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV67180720; called by muse, mutect2, varscan2
- GDF5 | c.1506G>T p.*502Yext*38 | Nonstop Mutation (SNP) | VAF 35/134 reads (26%) | catalogued as COSV65502441; called by muse, mutect2, varscan2
- GZMH | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs886499976, COSV53537589, COSV99361821; called by muse, mutect2, varscan2
- HBS1L | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV59021974; called by muse, mutect2, varscan2
- HCK | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 31/40 reads (78%) | catalogued as rs144393224, COSV52943439, COSV52947431, COSV99393875; called by muse, mutect2, varscan2
- HIVEP1 | c.1474A>T p.S492C | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65103598; called by muse, mutect2, varscan2
- HPSE2 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs751015169, COSV65186620; called by muse, mutect2, varscan2
- HTR3C | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs188090891; called by muse, mutect2, varscan2
- IKZF2 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as rs146574423; called by muse, varscan2
- IKZF2 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59581310; called by muse, mutect2, varscan2
- IKZF2 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59581320; called by muse, mutect2, varscan2
- KHDC4 | c.955G>T p.V319F | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64165381; called by muse, mutect2, varscan2
- KIAA1549 | c.5534G>A p.G1845D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54321566; called by muse, mutect2, varscan2
- KIF13A | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs753700328, COSV52449230; called by muse, mutect2, varscan2
- KLF17 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs377749405; called by muse, mutect2, varscan2
- KRT16 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV56968936; called by muse, mutect2, varscan2
- KRT18 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV66316426; called by muse, mutect2, varscan2
- LAMA4 | c.901G>A p.V301I (on ENST00000230538 / NM_001105206.3; = p.V294I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as rs200722112, COSV100037740; called by muse, mutect2, varscan2
- LDHD | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as COSV55581528; called by muse, mutect2, varscan2
- LRP1B | c.6415G>A p.V2139I | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1278204499, COSV101253683; called by muse, mutect2, varscan2
- LRRC37B | c.1151T>A p.L384Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV58953640; called by muse, mutect2, varscan2
- LRRIQ1 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV101279651; called by muse, mutect2
- MED12 | c.2753A>G p.Y918C | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61348567; called by muse, mutect2, varscan2
- MED13 | c.3934C>A p.Q1312K | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV67265466; called by muse, mutect2, varscan2
- MUC16 | c.34780A>C p.N11594H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.278); catalogued as COSV67479988; called by muse, mutect2, varscan2
- MYO9B | c.4461G>C p.K1487N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68281223; called by muse, mutect2, varscan2
- MYORG | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs1386042196, COSV52627828; called by muse, mutect2, varscan2
- NBEA | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs373518301; called by muse, mutect2, varscan2
- NCKAP1L | c.971A>G p.E324G | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99514605; called by muse, mutect2, varscan2
- NPR1 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs61737934; called by muse, mutect2, varscan2
- NSMAF | c.1664C>G p.T555R | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV50693439; called by muse, mutect2, varscan2
- NYAP2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); catalogued as rs376546506; called by muse, mutect2, varscan2
- OR10R2 | c.520T>G p.L174V | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.12); catalogued as COSV63768399, COSV63769239; called by muse, mutect2, varscan2
- OR13D1 | c.845T>C p.L282S | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59514388; called by muse, mutect2
- OR5T2 | c.1069A>T p.T357S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV57590257; called by muse, mutect2, varscan2
- PCDHB11 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100696916; called by muse, mutect2, varscan2
- PDE3A | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs754390819, COSV100761817; called by muse, mutect2, varscan2
- PDS5A | c.1352T>A p.L451Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57828589; called by muse, mutect2, varscan2
- PKD1L1 | c.6047T>A p.L2016H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV56972006; called by muse, mutect2, varscan2
- PLCD3 | c.1498G>C p.E500Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as COSV100504122; called by muse, mutect2, varscan2
- PLXDC2 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV65906535; called by muse, mutect2, varscan2
- PRKCB | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as COSV57790897; called by muse, mutect2, varscan2
- PWP1 | c.23C>G p.T8R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV101338787; called by muse, mutect2, varscan2
- RAB5A | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV56085144; called by muse, mutect2, varscan2
- RTRAF | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.951); catalogued as rs748105780, COSV55563668; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- SLIT2 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs200224686, COSV56560139; called by muse, mutect2, varscan2
- SPAG16 | c.1583T>G p.F528C | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59108613; called by muse, mutect2, varscan2
- SPRY1 | c.48C>G p.I16M | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV59338856; called by muse, mutect2, varscan2
- SPTA1 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs199544164; called by muse, mutect2, varscan2
- ST18 | c.1205-1G>C p.X402_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV52502002; called by muse, mutect2, varscan2
- TENM1 | c.1193A>T p.D398V | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as COSV64438008; called by muse, mutect2, varscan2
- TGIF1 | c.157del p.Q53Sfs*26 (on ENST00000330513 / NM_001374396.1; = p.Q73Sfs*26 on NM_003244.4) | Frame Shift Del (DEL) | VAF 23/40 reads (58%) | catalogued as COSV57906740; called by mutect2, pindel, varscan2
- THOC2 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV55551241; called by muse, mutect2, varscan2
- THSD7B | c.4825T>A p.*1609Kext*8 (on ENST00000272643; = p.*1607Kext*8 on NM_001316349.2) | Nonstop Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV99745716; called by muse, mutect2, varscan2
- TIAM2 | c.2998C>A p.P1000T | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as COSV59698785; called by muse, mutect2, varscan2
- TMPRSS11B | c.1177A>G p.K393E | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV60293275; called by muse, mutect2, varscan2
- TMPRSS7 | c.857G>A p.R286H (on ENST00000452346; = p.R160H on NM_001042575.2) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs746041967, COSV69981748, COSV69982427; called by muse, mutect2, varscan2
- TRIM50 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782346086, COSV53092910; called by muse, mutect2, varscan2
- TRIM9 | c.1199G>A p.W400* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | catalogued as COSV100031839, COSV53621431; called by muse, mutect2, varscan2
- TRPC7 | c.1885G>T p.G629C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61460652; called by muse, mutect2, varscan2
- TTN | c.22800A>C p.E7600D (on ENST00000591111; = p.E6673D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/130 reads (33%) | PolyPhen possibly damaging (0.737); catalogued as COSV100598344; called by muse, mutect2, varscan2
- UGGT2 | c.3143T>C p.L1048P | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65077096; called by muse, mutect2, varscan2
- VCAN | c.4769C>A p.S1590Y | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.286); catalogued as COSV54111202; called by muse, mutect2, varscan2
- XIRP2 | c.7964G>A p.R2655Q (on ENST00000628543; = p.R2830Q on NM_152381.6) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs368268974; called by muse, mutect2, varscan2
- ZDBF2 | c.3559C>G p.L1187V | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.531); catalogued as COSV65628205; called by muse, mutect2, varscan2
- ZNF302 | c.467A>G p.K156R (on ENST00000627982; = p.R76G on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.497); catalogued as COSV101416436; called by muse, mutect2, varscan2
- ZNF43 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV61684914; called by muse, mutect2, varscan2
- ZNF548 | c.887T>C p.F296S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV60241484; called by muse, mutect2, varscan2
- ZNF98 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV63338244; called by muse, mutect2, varscan2
- CETP | c.1465del p.L489Sfs*4 | Frame Shift Del (DEL) | VAF 27/77 reads (35%) | called by mutect2, pindel, varscan2
- FANCA | c.2397_2407del p.E800Gfs*16 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- GLI4 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2
- MYBL1 | c.673del p.Y225Tfs*19 | Frame Shift Del (DEL) | VAF 51/157 reads (32%) | called by mutect2, pindel, varscan2
- PAQR8 | c.237del p.W80Gfs*72 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- RGMB | c.153_156del p.A52Nfs*14 (on ENST00000513185 / NM_001366508.1; = p.A93Nfs*14 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/38 reads (63%) | called by pindel, varscan2
- ASXL1 | c.1356G>A p.G452= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV60114716; called by muse, mutect2, varscan2
- CCAR1 | c.1423C>A p.R475= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV56271853; called by muse, mutect2, varscan2
- CCKBR | c.756C>T p.D252= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as rs747685589, COSV58100637; called by muse, mutect2, varscan2
- CD36 | c.951T>A p.I317= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV59216371; called by muse, mutect2, varscan2
- CHD6 | c.7641T>C p.T2547= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100950642; called by muse, mutect2
- CSMD2 | c.9177C>T p.T3059= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs200819682, COSV53936557; called by muse, mutect2, varscan2
- CSMD3 | c.10998A>C p.S3666= (on ENST00000297405 / NM_001363185.1; = p.S3497= on NM_052900.3) | Silent (SNP) | VAF 85/247 reads (34%) | catalogued as rs1034229806, COSV99827190; called by muse, mutect2, varscan2
- CYP2A7 | c.297C>T p.S99= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as rs112051160, COSV99394319; called by muse, mutect2, varscan2
- FAM162B | c.441T>A p.A147= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV63920558, COSV63920612; called by muse, mutect2, varscan2
- FGFR1 | c.279C>T p.P93= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs781034707, COSV58340196; called by muse, mutect2, varscan2
- FRMPD2 | c.3027C>T p.C1009= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs536195026, COSV100563582; called by muse, mutect2, varscan2
- GJB7 | c.105C>A p.V35= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV51530776, COSV51531492, COSV99738764; called by muse, mutect2, varscan2
- KCNA5 | c.519C>T p.D173= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs752478454, COSV52907538; called by muse, mutect2, varscan2
- KRT1 | c.1920C>T p.S640= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs1436500384, COSV52868110; called by muse, mutect2, varscan2
- MCM6 | c.1491G>C p.T497= | Silent (SNP) | VAF 52/152 reads (34%) | catalogued as COSV99918793; called by muse, mutect2, varscan2
- NRXN1 | c.444G>A p.T148= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs765163297, COSV101280856, COSV68022177; ClinVar: likely benign; called by muse, mutect2
- NUMA1 | c.5898C>G p.R1966= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV52621907; called by muse, mutect2, varscan2
- PHF14 | c.2109C>G p.P703= | Silent (SNP) | VAF 130/268 reads (49%) | catalogued as rs1240854690, COSV68856373; called by muse, mutect2, varscan2
- PLEKHG4B | c.141C>T p.G47= (on ENST00000283426; = p.G403= on NM_052909.5) | Silent (SNP) | VAF 47/105 reads (45%) | catalogued as COSV52051470; called by muse, mutect2, varscan2
- RAB6D | c.399G>A p.K133= | Silent (SNP) | VAF 78/226 reads (35%) | catalogued as COSV72151679; called by muse, mutect2, varscan2
- RALGAPA2 | c.2391T>C p.P797= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as COSV52504296; called by muse, mutect2, varscan2
- RNFT2 | c.996G>T p.L332= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57488042; called by muse, mutect2, varscan2
- SCN3A | c.4983G>T p.L1661= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV99325977; called by mutect2, varscan2
- SLC30A5 | c.1860C>T p.I620= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs200016525; called by muse, mutect2, varscan2
- WARS2 | c.141C>A p.L47= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV52480792; called by muse, mutect2, varscan2
- FRMPD2B | n.444C>T | RNA (SNP) | VAF 150/858 reads (17%) | catalogued as rs781851473; called by muse, mutect2, varscan2
- GDF5 | c.*1C>T | 3'UTR (SNP) | VAF 36/134 reads (27%) | catalogued as COSV100976746; called by muse, mutect2, varscan2
